Surgical pathology report (de-identified scan), TCGA case TCGA-VS-A9UD, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VS-A9UD-01A (Primary Tumor).

(MM/DD/YYYY)

PATHOLOGY REPORT:

PRIMARY SITE: Cervix

1-"Fragment of uterine cervix":

Histologic grade 2 invasive squamous cell carcinoma.

Angiolymphatic invasion: not detected.

ICD-O-3

Carcinoma, squamous cell NOS
8070/3

Site Cervix NOS
C53.9

W 5/2/14

Source: NCI Genomic Data Commons file 5206553c-28a9-4801-bfdb-36dc043177c9 (TCGA-VS-A9UD.D0920498-DCB8-454A-A294-204A280D4129.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).